CPTAC case 14CO003 — Colon — Adenomas and Adenocarcinomas (CPTAC-2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/e965a8fa-a257-4fd7-8bbb-a0f134c0c7d3

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Prior malignancy: no.

Biospecimens (2 samples)
- Sample 79cabe71-f083-48ec-9b50-0c97a3: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
- Sample fd4edc52-09ef-4b01-be7c-f23f05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
